CCDI case PBCHKY — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/0c31b297-74d1-4c04-a725-0949cd41ebe7

Demographics
Sex at birth: male; Race: black or african american.

Diagnoses (1)
1. Subependymoma: ICD-O-3 morphology code: 9383/1; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 20.1 years (7,346 days).

Biospecimens (3 samples)
- Sample 0DS6KN: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DS6L3: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0DS6LH: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
